Gene-level copy-number profile of specimen HCM-CSHL-0907-C50-85B from HCMI case HCM-CSHL-0907-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 74.6 years (27,246 days).
Specimen HCM-CSHL-0907-C50-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5f9a0d3b-95f7-4554-b780-52e8f743b5c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0907-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/af0662c5-ae5e-4609-83be-97543da93557

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 96; copy number 2: 7,646; copy number 3: 19,135; copy number 4: 16,170; copy number 5: 9,528; copy number 6: 1,683; copy number 7: 1,928; copy number 8: 686; copy number 9: 812; copy number 10: 175; copy number 11: 45; copy number 12: 7; copy number 13: 19; copy number 14: 1; copy number 15: 3; copy number 17: 27; copy number 18: 34; copy number 19: 111; copy number 20: 16; copy number 21: 87; copy number 22: 17; copy number 26: 88; copy number 27: 22; copy number 28: 8; copy number 30: 46.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,061 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–153,310,718, 405 genes, copy number 18–30 (broad region; genes not listed).
- chr1:163,111,121–163,321,791, 1 gene, copy number 7 (within-gene range 6–7): RGS5.
- chr1:163,237,214–165,356,715, 24 genes, copy number 7: AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1.
- chr2:130,830,978–131,353,709, 14 genes, copy number 7 (within-gene range 5–7): AC133785.1, ARHGEF4, AC112786.1, AC112786.2, SMIM39, FAM168B, PLEKHB2, NEK2P4, AC009477.1, NF1P8, AC131180.1, MED15P8, POTEE, RNU6-127P.
- chr2:131,303,037–131,355,683, 1 gene, copy number 7 (within-gene range 5–7): AC073869.5.
- chr2:131,335,502–131,355,769, 1 gene, copy number 7 (within-gene range 5–7): AC073869.7.
- chr2:160,099,667–162,838,767, 40 genes, copy number 9: ITGB6, AC092153.1, LINC02478, RBMS1, MIR4785, AC096656.1, RN7SL423P, AC009313.1, TANK-AS1, TANK, AC009299.2, LINC01806, AC009299.1, PSMD14, MXRA7P1, RNA5SP108, TBR1, AC009487.1, AC009487.2, SLC4A10, AC009487.3, AHCTF1P1, AC092654.1, AC062022.1, AC062022.2, KRT18P46, RPEP5, DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109, KCNH7-AS1.
- chr4:705,748–3,040,760, 72 genes, copy number 8 (broad region; genes not listed).
- chr4:3,044,101–3,074,538, 4 genes, copy number 8: RNU6-204P, HTT-AS, AL390065.2, AL390065.1.
- chr4:16,501,541–20,752,907, 32 genes, copy number 7 (within-gene range 2–7): LDB2, AC104656.1, AC106894.1, MTND5P4, LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, LAP3, AC006160.1, MED28, FAM184B, DCAF16, NCAPG, LCORL, KRT18P63, AC093898.1, AC093871.1, AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL.
- chr5:38,258,409–45,895,970, 112 genes, copy number 7 (broad region; genes not listed).
- chr6:166,099,665–167,825,145, 50 genes, copy number 7 (within-gene range 6–7): AL627443.1, AL627443.2, TBXT, LNCDAT, RNU6-153P, AL121956.6, AL121956.1, GNG5P1, AL121956.5, PRR18, SFT2D1, HNRNPA1P49, MPC1, AL022069.1, AL022069.2, RPS6KA2, RPS6KA2-IT1, MIR1913, RAMACL, AL023775.2, AL023775.1, AL159163.1, RPS6KA2-AS1, RNASET2, Z94721.1, Z94721.3, MIR3939, CEP43, Z94721.2, CCR6, AL121935.1, AL121935.2, TCP10L2, GPR31, AL121935.3, AL353747.1, HPAT5, AL353747.3, AL353747.2, UNC93A, TTLL2, AL021331.1, TCP10L3, LINC02538, AL356123.2, LINC02487, AL009178.1, LINC01558, AL009178.2, AL009178.3.
- chr7:94,278,680–108,952,666, 371 genes, copy number 7–12 (broad region; genes not listed).
- chr7:157,539,056–158,587,823, 1 gene, copy number 9 (within-gene range 3–9): PTPRN2.
- chr7:157,854,529–159,233,377, 17 genes, copy number 8–9: PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:37,695,782–41,032,998, 79 genes, copy number 10 (broad region; genes not listed).
- chr8:55,696,424–69,104,242, 197 genes, copy number 7–10 (broad region; genes not listed).
- chr8:77,399,072–145,066,685, 1,035 genes, copy number 7–15 (broad region; genes not listed).
- chr9:7,477,045–7,478,320, 1 gene, copy number 11: RPL4P5.
- chr10:14,061–38,762,491, 644 genes, copy number 7 (broad region; genes not listed).
- chr11:89,764,884–89,789,733, 5 genes, copy number 9–12: AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3.
- chr12:12,310–11,395,566, 421 genes, copy number 8–9 (within-gene range 4–10) (broad region; genes not listed).
- chr12:17,479,446–44,389,762, 379 genes, copy number 7–10 (broad region; genes not listed).
- chr12:44,508,275–46,876,784, 32 genes, copy number 8–15 (within-gene range 4–15): NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1.
- chr12:48,559,882–48,765,790, 10 genes, copy number 10–11: OR5BS1P, LALBA, OR11M1P, KANSL2, SNORA2C, MIR1291, SNORA2A, SNORA2B, CCNT1, TEX49.
- chr13:81,114,866–81,691,072, 6 genes, copy number 7–8: DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.
- chr13:83,145,540–84,020,762, 6 genes, copy number 7–8: AL512782.1, RNU6-67P, SLITRK1, AL355481.1, VENTXP2, UBE2D3P4.
- chr13:95,310,830–98,455,176, 42 genes, copy number 8–9 (within-gene range 3–9): RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24, HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, RPL7AP61, AL356580.1, IPO5, FTLP8, FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1.
- chr13:107,465,984–107,933,503, 5 genes, copy number 7: AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1.
- chr13:108,480,226–111,901,264, 52 genes, copy number 14–21: HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1, TEX29, AL359649.1, LINC02337, LINC00354.
- chr20:63,400,208–63,472,677, 2 genes, copy number 7 (within-gene range 6–7): KCNQ2, AL353658.1.

Autosomal genes at a single copy (total copy number 1): 96. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
